Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A6DJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A6DJ-01A (Primary Tumor).

[page 1 of 8]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Mandible, proximal margin, biopsy
- No tumor seen

B: Mandible, distal margin, biopsy
- No tumor seen

C: Soft tissue, posterior margin, biopsy
- No tumor seen

D: Soft tissue, medial margin, biopsy
- No tumor seen

E: Soft tissue, anterior margin, biopsy
- No tumor seen

F: Soft tissue, lateral margin, biopsy
- No tumor seen

G: Soft tissue, deep margin, biopsy
- No tumor seen

H: Lymph nodes, level 2B, left cervical, regional resection
- No tumor seen in 10 lymph nodes (0/10)

I: Lymph nodes, level 2A, left cervical, regional resection
- Metastatic squamous cell carcinoma in 1 of 20 lymph nodes (1/20); maximum size of metastasis 0.3 cm; negative for extracapsular extension

J: Lymph nodes, level 3, left cervical, regional resection
- No tumor seen in 17 lymph nodes (0/17)

K: Lymph nodes, level 4, left cervical, regional resection
- No tumor seen in 9 lymph nodes (0/9)

L: Lymph nodes, level 6, bilateral, cervical, regional resection
- No tumor seen in 2 lymph nodes (0/2)

M: Mandible, left, hemimandibulectomy with level 1 lymph nodes

Tumor histologic type/subtype: Invasive moderately

ICD-O-3
Carcinoma, squamous cell,
keratinizing NOS 8071/3
Site ^{cell} Alveolar ridge mucosa ^{NOS}
C03.9
path mandible C41.1
JW 5/21/13

[page 2 of 8]
differentiated keratinizing squamous cell carcinoma

Primary site: Left mandible

Size: Maximum tumor size 6.0 cm by gross examination

Extent of invasion:

Angiolymphatic invasion: Present

Perineural Invasion: Present

Bone invasion: Present

P16 IHC status: Pending (M6)

HR HPV ISH status: Pending (M6)

Carcinoma in situ: Present

Surgical Margins: Soft tissue margins negative for definite involvement by carcinoma; closest margin is lateral posterior soft tissue margin, less than 0.1 cm.

Anterior mandible bone margin, pending decalcification, to be reported in an addendum; Posterior mandible bone margin negative for tumor

Lymph nodes: Metastatic squamous cell carcinoma in 3 of 8 lymph nodes in this specimen from left level 1 (3/8); See additional separately submitted lymph nodes in specimens H-L and N-P

Size of largest metastasis: 1.8 cm (specimen M)

Extra-capsular extension: Not identified

Other significant findings: Benign submandibular gland

AJCC PATHOLOGIC TNM STAGE: pT4a pN2c

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

N: Lymph nodes, level 3, right cervical, regional resection
- No tumor seen in 25 lymph nodes (0/25)

O: Lymph nodes, level 2, right cervical, regional resection
- Metastatic squamous cell carcinoma in 1 of 2 lymph nodes (1/2); maximum size of metastasis 0.6 cm; negative for

[page 3 of 8]
extracapsular extension.

P: Lymph nodes, level 1, right cervical, regional resection

- Metastatic squamous cell carcinoma in 3 of 8 lymph nodes (3/8); maximum size of metastasis 0.8 cm; negative for extracapsular extension.

- Benign submandibular gland

Q: Teeth, #31 and #32, extraction

- Teeth for gross identification only

- Fragments of benign bone, soft tissue, and reactive mucosa with acute and chronic inflammation

Comment:

The frozen section diagnoses are confirmed.

Intraoperative Consult Diagnosis:

An intraoperative consultation is requested by Dr. in on

FSA1: Proximal mandible margin, biopsy

- No tumor seen

FSB1: Distal mandible margin, biopsy

- No tumor seen

FSC1: Posterior margin, biopsy

- No tumor seen

FSD1: Medial margin, biopsy

- No tumor seen

FSE1: Anterior margin, biopsy

- No tumor seen

FSF1: Lateral margin, biopsy

- No tumor seen

FSG1: Deep margin, biopsy

- No tumor seen

Drs. on at (A-G).

Frozen Section Pathologist:, MD

[page 4 of 8]
Clinical History:

The patient is a -year-old man with a history of left mandible squamous cell carcinoma.

Gross Description:

Specimen A is received in an appropriately labeled container additionally labeled "proximal mandible margin" and contains a 3 x 2 x 2 mm tan/pink soft tissue fragment, totally submitted in FSA1,

Specimen B is received in an appropriately labeled container additionally labeled "distal mandible margin" and contains a 3 x 2 x 2 mm tan/pink soft tissue fragment, totally submitted in FSB1,

Specimen C is received in an appropriately labeled container additionally labeled "posterior margin" and contains a 9 x 4 x 4 mm tan/pink soft tissue fragment, totally submitted in FSC1,

Specimen D is received in an appropriately labeled container additionally labeled "medial margin" and contains a 9 x 3 x 3 mm tan/pink soft tissue fragment, totally submitted in FSD1,

Specimen E is received in an appropriately labeled container additionally labeled "anterior margin" and contains an 11 x 4 x 3 mm tan/pink soft tissue fragment, totally submitted in FSE1,

Specimen F is received in an appropriately labeled container additionally labeled "lateral margin" and contains an 10 x 2 x 2 mm

Specimen G is received in an appropriately labeled container additionally labeled "deep margin" and contains an 10 x 8 x 5 mm tan/pink soft tissue fragment, totally submitted in FSG1,

Specimen H is labeled "left cervical lymph node, level 2B" and holds a 3.5 x 2.2 x 0.5 cm fragment of yellow fibrofatty tissue. Within the tissue, there are multiple lymph node candidates up to 0.4 cm in greatest dimension, H1-H2, multiple per cassette,

Specimen I is labeled "left cervical lymph node, level 2A" and holds a 5.5 x 4.2 x 1.1 cm fragment of yellow firm fibrofatty tissue. Within the tissue, there are multiple palpable lymph nodes the largest is 1.7 cm in greatest dimension.

[page 5 of 8]
Block Summary:

I1-I3 - Multiple lymph nodes, each cassette

I4-I5 - Three lymph nodes, each cassette, all bisected, one non-inked, one inked black, the other inked green

I6 - One lymph node, serially sectioned

Specimen J is labeled "left cervical lymph node, level 3" and holds a 4.7 x 3.1 x 1.2 cm fragment of yellow fibrofatty tissue. Within the tissue, there are multiple lymph node candidates, the largest is 1.5 cm.

Block Summary:

J1-J2 - Multiple lymph node candidates, each cassette

J3-J4 - Two lymph nodes, each cassette, one inked black, the other not inked, both bisected

J5 - Two lymph nodes, fat remains in formalin

Specimen K is labeled "left cervical lymph node, level 4" and holds a 4.7 x 2.5 x 0.6 cm fragment of yellow lobulated fibrofatty tissue. Within the tissue, there are multiple lymph node candidates, the largest is 1 cm in greatest dimension.

Block Summary:

K1-K3 - Multiple lymph node candidates, each cassette

Tissue remains in formalin.

Specimen L is labeled "bilateral cervical lymph nodes, level 6" and holds a 4.7 x 2.2 x 1.0 cm fragment of yellow fibrofatty tissue. Within the tissue, there is a single palpable lymph node which is 5 mm in greatest dimension.

Block Summary:

L1 - Lymph node, bisected

L2-L6 - Remaining fat,

Specimen M is labeled "left hemimandible with level 1 lymph nodes" and holds a left hemimandibulectomy specimen. The specimen is approximately 10.5 cm from anterior to posterior x 4.7 cm lateral to midline x 5.2 cm from superior to inferior. The mandible is transected posteriorly through the ramus resulting in two surgical margins, 1 superior and 1 anterior (2.5 and 2.1 cm each). The anterior mandibular margin is 3.0 cm. The mandible is notable for two teeth present anteriorly immediately posterior to the second tooth. The tumor extends 6.0 cm from anterior to posterior and 2.2 cm from lateral edge to midline.

[page 6 of 8]
There is a tan firm mass, centered on the mandible and extending into the buccal mucosa. The mucosal margins are differentially inked anterior/lateral/posterior edge/black, anterior midline and posterior edge/blue. The surrounding soft tissue lateral inferior midline and posterior is inked green. The mass at its closest approach to the mucosal margins is 0.4 cm from the blue inked midline, black inked anterior, black inked posterior, and is greater than 1 cm from the black inked lateral edge.

Along the inner edge of the mandible, there are four palpable lymph nodes, ranging from 0.5 to 3.0 cm. The lymph nodes lift freely from the bone of the mandible and are surrounded by yellow lobulated fat and yellow lobulated glandular tissue. The tissue along the lateral edge of the mandible is comprised of red/brown muscle. The mass on section comes to within 0.5 cm of this muscle.

Sectioning reveals that the mass extends into the mandible, coming to within 2.5 cm of the anterior bone margin and greater than 4 cm from the posterior bone margin.

A portion of tumor is submitted to tissue procurement.

A photograph of the specimen is taken.

Block Summary:

- M1 - Anterior midline mucosal margin, perpendicular
- M2 - Midline mucosal margin, perpendicular
- M3 - Midline and lateral posterior mucosal margin, perpendicular
- M4 - Anterior mucosal margin, perpendicular adjacent to second tooth
- M5 - Anterior lateral mucosal margin, perpendicular
- M6 - Lateral and mucosal margin, perpendicular
- M7 - Mass with respect to lateral anterior green inked soft tissue margin, perpendicular
- M8 - Mass with respect to lateral posterior green inked margin, perpendicular
- M9 - Inferior soft tissue margin, en face
- M10 - One lymph node, bisected
- M11 - Representative section of lymph node, along inner edge of mandible to include adjacent glandular tissue
- M12 - Section of lymph node along inner aspects with surrounding yellow lobulated fibrofatty tissue
- M13 - Lymph node along inner lining of mandible, representative
- M14 - Representative of glandular tissue to include lymph nodes
- M15 - One lymph node, bisected
- M16-M17-Anterior mandibular bone margin, en face, following

[page 7 of 8]
decalcification

M18 - Posterior mandibular bony margin, on face, following decalcification

M19-M20- Representative sections of mandible to include mass involvement following decalcification

Specimen N is labeled "right cervical lymph node, level 3" and holds a 4.5 x 3.5 x 0.9 cm fragment of yellow firm fibrofatty tissue. Within the tissue, there are multiple lymph nodes up to 1.1 cm in greatest dimension.

Block Summary:

N1-N3 - Multiple lymph nodes each cassette

N4-N6 - One lymph node, each cassette, each bisected

Fat remains in formalin.

Specimen O is labeled "right cervical neck, level 2" and holds a 4.9 x 2.5 x 1.1 cm fragment of yellow fibrofatty tissue. Within the tissue, there are multiple lymph node candidates, the largest is 2.5 cm.

Block Summary:

O1 - One lymph node, trisected

O2 - One lymph node, bisected

O3-O6 - Remaining fibrofatty tissue,

Specimen P is labeled "right cervical lymph node, level 1" and holds a 19.3 gram, 5.2 x 4.0 x 2.0 cm fragment of yellow fibrofatty tissue. Within the tissue, there is a 4.0 x 2.7 x 1.0 cm gland. The outer surface is tan and smooth. On section the gland is yellow, lobulated and unremarkable. Within the adjacent fibrofatty tissue, there are multiple lymph node candidates, the largest is 2 cm in greatest dimension.

Block Summary:

P1-P6 - One lymph node, each cassette, each sectioned

P7 - Two lymph nodes

P8 - Representative section of gland

Specimen Q is labeled "teeth #31 and 32 and holds two teeth roughly 1.7 x 0.6 x 0.5 cm. The enamel of both teeth is worn down and discolored tan to brown.

There is a small amount of soft tissue attached at the root enamel junction. This tissue is submitted in Q1. The teeth are retained in formalin for gross exam only, which is performed by Dr.

[page 8 of 8]
Addendum

Add results of addition sections following decalcification.

Addendum Comment

M: Mandible, left hemimandibulectomy with level 1 lymph nodes

- Anterior mandible bone margin negative for tumor.
- p16 immunohistochemistry and high risk HPV in situ hybridization stains are negative. Appropriate controls are performed.

HPA Discrepancy		✓

Source: NCI Genomic Data Commons file 8496b30c-f390-4191-a8ee-ede52ce424ca (TCGA-BA-A6DJ.6395BB34-43EF-4FB8-BF58-346261E40732.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).